Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A6L9, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A6L9-06A (Metastatic).

Patient ID:

Surgical Date:

Gross Description: 5 left inguinal lymph nodes are black-brown in cutting section, 3.5x2.5x2.5cm in maximum size.

Microscopic Description: Lymph node architectures are replaced by tumor cells. Tumor is composed of spindle or oval tumor cells with quite scant cytoplasm. Tumor cells have a quite low nucleo-cytoplasmic ratio. Nucleus varies in shape and size with large esinophilic nucleoli. Mitotic figures are common. Tumor is necrotic. Lymphocytic tissue are seen.

Diagnosis Details: Metastatic neoplasm, malignant melanoma

Comments:

Formatted Path Reports: Diagnosis: Metastatic neoplasm, malignant melanoma

Tumor size: 3.5 x 2.5 x 2.5cm

Tumor location: Lymph nodes, inguinal

*ICD-O-3
Melanoma, malignant NOS
8720/3
Site Inguinal lymph node
2775
JW 6/25/13*

Reviewed Initials:	JW 6/23/13	

Source: NCI Genomic Data Commons file 53072c0d-6276-428a-8967-3fca1ebfe442 (TCGA-EB-A6L9.B2E9DBA6-54D6-42D5-B48E-185CE46054B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).